Somatic mutation profile of tumor specimen TCGA-2G-AAGC-01A (aliquot TCGA-2G-AAGC-01A-21D-A42Y-10) from TCGA case TCGA-2G-AAGC, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage IS; Age at diagnosis: 28.8 years (10,518 days).
Specimen TCGA-2G-AAGC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72d07802-3a52-421f-92ee-dcbba932598a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAGC-10A (Blood Derived Normal), aliquot TCGA-2G-AAGC-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da796274-dc3f-41bb-83de-acf13e26b0af

The open-access MAF lists 17 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, Silent 2, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH24 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs955239180, COSV52975829; called by muse, mutect2, varscan2
- FNDC1 | c.2279G>A p.R760Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); catalogued as rs771304162, COSV51932431, COSV51939389, COSV51951886; called by mutect2, varscan2
- SECISBP2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV60528874; called by muse, mutect2, varscan2
- ZNF541 | c.3910C>T p.R1304* | Nonsense Mutation (SNP) | VAF 22/81 reads (27%) | catalogued as COSV54544611; called by muse, mutect2, varscan2
- ABCC1 | c.3885C>A p.F1295L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.04); called by muse, mutect2
- CCDC142 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCRLB | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- FRMPD1 | c.4219G>A p.A1407T | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.037); called by muse, mutect2
- GJA9 | c.1005_1006del p.L336* | Frame Shift Del (DEL) | VAF 28/143 reads (20%) | called by pindel, varscan2
- IFNAR1 | c.524G>A p.G175D | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- IPO11 | c.764G>A p.S255N | Missense Mutation (SNP) | VAF 169/521 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTBP2 | c.206T>A p.L69H (on ENST00000426398 / NM_001300986.2; = p.L61H on NM_021190.4) | Missense Mutation (SNP) | VAF 52/199 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- RIMS1 | c.861G>T p.K287N | Missense Mutation (SNP) | VAF 29/285 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ADAM32 | c.1269T>G p.T423= | Silent (SNP) | VAF 31/114 reads (27%) | called by muse, mutect2, varscan2
- ANKRD50 | c.636G>A p.G212= | Silent (SNP) | VAF 34/140 reads (24%) | called by muse, mutect2, varscan2
- RPGR | c.2520+83G>C | Intron (SNP) | VAF 49/134 reads (37%) | called by muse, mutect2, varscan2
- SPTBN1 | c.148+32212A>G | Intron (SNP) | VAF 56/263 reads (21%) | called by muse, mutect2, varscan2
